Somatic mutation profile of tumor specimen 0DCJR7 from CCDI case PBBMJP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 9.9 years (3,628 days).
Specimen 0DCJR7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a585d2a-de1e-4282-a2ce-97813fd90619.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCJR5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09d8c479-9a32-402a-a849-304e2a000a9a

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPHP4 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 226/546 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1288396418, COSV65397616; called by muse, mutect2, varscan2
- TMEM205 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 460/997 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1301481073, COSV61514607; called by muse, mutect2, varscan2
- FGFR4 | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 186/535 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- MYO18B | c.34C>G p.Q12E | Missense Mutation (SNP) | VAF 389/901 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OGDHL | c.1388A>G p.N463S | Missense Mutation (SNP) | VAF 484/1083 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POF1B | c.201C>G p.D67E | Missense Mutation (SNP) | VAF 433/895 reads (48%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAMTA1 | c.3876A>T p.G1292= | Silent (SNP) | VAF 142/788 reads (18%) | called by muse, varscan2
- L3MBTL4 | c.1101G>A p.T367= | Silent (SNP) | VAF 361/1186 reads (30%) | catalogued as rs541961038, COSV53114835; called by muse, mutect2, varscan2
- METTL6 | c.132T>C p.N44= | Silent (SNP) | VAF 610/1239 reads (49%) | catalogued as rs768972630, COSV67542694; called by muse, mutect2, varscan2
- TMEM252 | c.390C>G p.G130= | Silent (SNP) | VAF 355/753 reads (47%) | called by muse, mutect2, varscan2
- EMC2 | c.363+46A>G | Intron (SNP) | VAF 361/809 reads (45%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.1393-69C>T | Intron (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2, varscan2
